Somatic mutation profile of tumor specimen C3N-02595-01 (aliquot CPT0181810007) from CPTAC case C3N-02595, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 41.3 years (15,077 days).
Specimen C3N-02595-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a78a0af9-9eae-4670-80de-89a765334505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02595-31 (Blood Derived Normal), aliquot CPT0181870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb5cb711-f3ac-468f-a6e2-eeb0a726d879

The open-access MAF lists 1,452 somatic variants for this specimen: 949 protein-altering or splice-affecting, 298 silent, 205 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 618, Silent 298, Frame Shift Del 215, Intron 113, Frame Shift Ins 43, Nonsense Mutation 29, RNA 25, 3'UTR 24, 5'UTR 20, In Frame Del 19, Splice Site 13, Splice Region 12.

Variants (750 of 1,452; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 34/270 reads (13%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 39/252 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- DYNC1H1 | c.4532C>T p.P1511L | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327664377, COSV64134818; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1172T>G p.M391R | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as rs387906677, CM121907, COSV60651291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 38/207 reads (18%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HEXA | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 181/512 reads (35%) | catalogued as rs786204585, CM113520, COSV51507538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | catalogued as rs782460038; ClinVar: pathogenic; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 43/313 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1359_1361del p.E453del | In Frame Del (DEL) | VAF 21/108 reads (19%) | hotspot (GDC flag); catalogued as rs587776933; called by pindel, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPM3 | c.2980G>A p.V994M (on ENST00000357533 / NM_001366142.2; = p.V837M on NM_020952.6) | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1564493599, COSV62594565; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAMDC | c.36del p.Q13Kfs*2 | Frame Shift Del (DEL) | VAF 32/197 reads (16%) | catalogued as COSV59022188; called by mutect2, pindel, varscan2
- ABCA1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 69/501 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs201642049; called by muse, mutect2, varscan2
- ABCA12 | c.4676G>T p.G1559V (on ENST00000272895 / NM_173076.3; = p.G1241V on NM_015657.3) | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457513156, CM120805; called by muse, mutect2, varscan2
- ABCD1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99497762; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.963G>T p.E321D | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV68344696; called by muse, varscan2
- ABT1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1554144825, COSV99223057; called by muse, mutect2, varscan2
- ACE | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs371833006; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 15/103 reads (15%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ACTL7A | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs369812697; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 26/169 reads (15%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY4 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766880309; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs760140619; called by mutect2, varscan2
- ADHFE1 | c.501del p.I168Lfs*14 | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | catalogued as rs1323475344; called by mutect2, pindel, varscan2
- ADNP | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs780464991; called by muse, mutect2, varscan2
- ADNP2 | c.2447G>A p.G816D | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1319000906; called by muse, mutect2, varscan2
- ADRA1D | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745387589, COSV65240474; called by muse, mutect2, varscan2
- AGRN | c.2149G>A p.V717M | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1318418672, COSV101038853; called by muse, mutect2, varscan2
- AIPL1 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs774143285, COSV51506971; called by muse, mutect2, varscan2
- AKR7A3 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 154/400 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs369200663, COSV64389244; called by muse, mutect2, varscan2
- ALX3 | c.313del p.Q105Sfs*88 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs759127084; called by mutect2, pindel, varscan2
- ANK2 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261943601, COSV52154963; called by muse, mutect2, varscan2
- ANKK1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs778503691, COSV100392904, COSV58273176; called by muse, mutect2, varscan2
- ANKLE1 | c.928C>T p.H310Y (on ENST00000394458; = p.H256Y on NM_152363.6) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs141686689; called by muse, mutect2, varscan2
- ANKRD11 | c.6715G>A p.V2239M | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs924433707; called by muse, mutect2, varscan2
- ANKRD18A | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs371182398; called by muse, mutect2, varscan2
- ANKRD36C | c.3613G>A p.G1205S | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1410269754, COSV101337180; called by muse, mutect2, varscan2
- ANKRD9 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs909376500; called by muse, mutect2, varscan2
- AP5Z1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as rs1197385837; called by muse, mutect2, varscan2
- APLP2 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs367821777; called by muse, mutect2, varscan2
- APLP2 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs200359846; called by muse, mutect2, varscan2
- ARFGEF2 | c.1775-1G>T p.X592_splice | Splice Site (SNP) | VAF 40/250 reads (16%) | catalogued as COSV100904364; called by muse, mutect2, varscan2
- ARHGAP21 | c.4756G>T p.D1586Y | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57608174; called by muse, mutect2, varscan2
- ARHGAP35 | c.2914dup p.R972Pfs*40 | Frame Shift Ins (INS) | VAF 21/188 reads (11%) | catalogued as rs1365296949; called by pindel, varscan2
- ARHGEF16 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs531452977; called by muse, mutect2, varscan2
- ARID1A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.211); catalogued as rs754046530, COSV61389078; called by muse, mutect2, varscan2
- ARID2 | c.4390C>T p.R1464C | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.993); catalogued as rs760589011, COSV57602539; called by muse, mutect2, varscan2
- ARL14EP | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs1253508906, COSV99955973; called by muse, mutect2, varscan2
- ARMCX3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV57869709; called by muse, mutect2
- ARSI | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99074971; called by muse, mutect2, varscan2
- ASL | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 206/629 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs778692269; called by muse, mutect2, varscan2
- ASTN1 | c.2380A>G p.M794V | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as rs776171100; called by muse, mutect2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 48/177 reads (27%) | catalogued as rs1268253442; called by pindel, varscan2
- B4GALNT4 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1211115506, COSV57323112; called by muse, mutect2, varscan2
- BACH2 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 73/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57609411; called by muse, mutect2, varscan2
- BAHCC1 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782637162; called by muse, mutect2, varscan2
- BAIAP2L1 | c.759del p.V254Cfs*10 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as COSV99135180; called by mutect2, pindel, varscan2
- BARHL2 | c.376dup p.Q126Pfs*20 | Frame Shift Ins (INS) | VAF 44/156 reads (28%) | catalogued as rs747119215; called by mutect2, varscan2
- BCAT2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60274023; called by muse, mutect2, varscan2
- BCCIP | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.435); catalogued as rs1231035624; called by muse, mutect2, varscan2
- BCR | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.207); catalogued as rs762056930; called by muse, mutect2, varscan2
- BICRA | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs755501951; called by muse, mutect2, varscan2
- BRD4 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 162/469 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs199540579; called by muse, mutect2, varscan2
- BTAF1 | c.4954C>T p.Q1652* | Nonsense Mutation (SNP) | VAF 36/510 reads (7%) | catalogued as COSV99795947; called by muse, mutect2
- C14orf39 | c.1349dup p.F451Vfs*4 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | catalogued as rs776870689; called by mutect2, varscan2
- C16orf96 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 147/418 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs1315803508; called by muse, mutect2, varscan2
- C5orf47 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.08); catalogued as rs1481467890, COSV60864278; called by muse, mutect2, varscan2
- C6orf118 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV57816253; called by muse, mutect2, varscan2
- C8orf33 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs369052825; called by muse, mutect2, varscan2
- CABIN1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1251403962; called by muse, mutect2, varscan2
- CACNA2D4 | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.492); catalogued as rs370089468; called by muse, mutect2, varscan2
- CACNG3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV50065182, COSV99135432; called by muse, mutect2, varscan2
- CAD | c.6568G>A p.E2190K | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53027382; called by muse, mutect2
- CAGE1 | c.1175C>T p.T392M (on ENST00000512086; = p.T256M on NM_205864.3) | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs749281807; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 75/231 reads (32%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1208010589, COSV57907429; called by muse, mutect2, varscan2
- CAPN8 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs1023663337; called by muse, mutect2, varscan2
- CASZ1 | c.3328G>A p.V1110M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs1445358610, COSV59740024; called by muse, mutect2, varscan2
- CC2D1B | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1055012439, COSV99429776; called by muse, mutect2, varscan2
- CCDC78 | c.1118dup p.T374Nfs*97 | Frame Shift Ins (INS) | VAF 27/186 reads (15%) | catalogued as rs1567315083; called by mutect2, pindel, varscan2
- CCDC88B | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1361419527; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | catalogued as rs773752200; called by mutect2, varscan2
- CCDC96 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59509462; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs761073142; called by mutect2, varscan2
- CCR7 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99878642, COSV99878891; called by muse, mutect2, varscan2
- CDC42BPB | c.3193G>A p.V1065M | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.658); catalogued as rs1220016248, COSV63474334, COSV63477192; called by muse, mutect2, varscan2
- CDC5L | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101014844, COSV65176120; called by muse, mutect2, varscan2
- CELA3B | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs766477609; called by muse, mutect2, varscan2
- CEP170B | c.2710A>G p.M904V (on ENST00000453495; = p.M833V on NM_015005.3) | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1288145924; called by muse, mutect2, varscan2
- CES4A | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1200511877; called by muse, mutect2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 32/162 reads (20%) | catalogued as rs763364101; called by mutect2, varscan2
- CGB7 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1038708554; called by muse, mutect2, varscan2
- CHAMP1 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100778758; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD1 | c.657T>G p.D219E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs371007031; called by muse, mutect2, varscan2
- CHD6 | c.8137G>A p.D2713N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1047269026, COSV64694410; called by muse, mutect2, varscan2
- CIITA | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs199476070; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CLASP1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs367922299; called by muse, mutect2, varscan2
- CLASRP | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1232523865; called by muse, varscan2
- CLEC18A | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1431509593, COSV55344522; called by muse, mutect2, varscan2
- CLIP3 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs759444972, COSV53325165; called by muse, varscan2
- CLK2 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.885); catalogued as rs761469877; called by muse, mutect2, varscan2
- CLMN | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs147953886; called by muse, mutect2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 18/189 reads (10%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTNAP3 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 74/406 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1440673626; called by muse, mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 52/308 reads (17%) | catalogued as COSV100615079, COSV62186140; called by pindel, varscan2
- COL5A1 | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65666211; called by muse, mutect2, varscan2
- COL5A3 | c.3238del p.D1080Mfs*64 | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | catalogued as COSV53418826; called by mutect2, pindel, varscan2
- COL7A1 | c.8308C>T p.R2770W | Missense Mutation (SNP) | VAF 74/702 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs147462803; called by muse, mutect2, varscan2
- CORO7 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1038042434; called by muse, mutect2, varscan2
- CRX | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1056691132; called by muse, mutect2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 70/239 reads (29%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSF2RB | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 126/349 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as COSV53259885; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 32/193 reads (17%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.7777C>T p.R2593C (on ENST00000297405 / NM_001363185.1; = p.R2489C on NM_052900.3) | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52164475, COSV52212859; called by muse, mutect2, varscan2
- CSPG4 | c.418del p.L140* | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as rs1212043883; called by mutect2, varscan2
- CTR9 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1397467879, COSV63727972; called by muse, mutect2, varscan2
- CTU1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294782839, COSV101361829; called by muse, mutect2, varscan2
- CYB5R4 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.038); catalogued as rs201084572; called by muse, mutect2, varscan2
- CYP46A1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.065); catalogued as COSV99952402; called by muse, mutect2, varscan2
- DCAF12L1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs377390890, COSV64421336; called by muse, mutect2, varscan2
- DCDC1 | c.3414del p.L1140Sfs*36 (on ENST00000597505 / NM_001367979.1; = p.L247Sfs*36 on NM_020869.3) | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as COSV60307531, COSV60312679; called by mutect2, pindel, varscan2
- DCHS1 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1385876990, COSV55041839; called by muse, mutect2, varscan2
- DDI1 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215205738; called by muse, mutect2, varscan2
- DDR1 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV61322983; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 56/175 reads (32%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX50 | c.1459A>G p.I487V | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV101007241; called by muse, mutect2, varscan2
- DHCR7 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 190/519 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs140400648, COSV100831972; called by muse, mutect2, varscan2
- DIDO1 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99826917; called by muse, mutect2, varscan2
- DIPK1B | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012248039; called by muse, mutect2, varscan2
- DISP1 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.283); catalogued as rs762072719, COSV52663490; called by muse, mutect2, varscan2
- DLAT | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs782431216; called by muse, mutect2, varscan2
- DLC1 | c.2254G>A p.A752T (on ENST00000276297 / NM_001348081.2; = p.A315T on NM_006094.5) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.411); catalogued as rs764061122; called by muse, varscan2
- DLGAP3 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs952820030; called by muse, mutect2
- DNAH17 | c.6941C>T p.T2314M | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753233839; called by muse, mutect2, varscan2
- DNAH8 | c.13266del p.K4423Rfs*39 | Frame Shift Del (DEL) | VAF 47/277 reads (17%) | catalogued as COSV59422950; called by mutect2, pindel, varscan2
- DOP1B | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750339936, COSV67693181; called by muse, mutect2, varscan2
- DOT1L | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs370276763; called by muse, mutect2, varscan2
- DSCAML1 | c.6137dup p.A2047Sfs*8 (on ENST00000321322; = p.A1987Sfs*8 on NM_020693.4) | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | catalogued as rs1345834453; called by mutect2, varscan2
- DYNC1H1 | c.12788G>A p.R4263H | Missense Mutation (SNP) | VAF 122/668 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs762441496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs766532365, COSV58173698, COSV58178759; called by muse, mutect2, varscan2
- EDNRB | c.1424C>A p.A475D (on ENST00000377211 / NM_001201397.1; = p.A385D on NM_000115.5) | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100526388; called by muse, mutect2
- EIF3A | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); catalogued as rs770042179; called by muse, mutect2
- ELFN2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.287); catalogued as rs760630459; called by muse, mutect2, varscan2
- EPS8L2 | c.1412del p.P471Rfs*49 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV59350488; called by mutect2, pindel
- ERAP1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as rs909816083; called by muse, mutect2
- ERBB4 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs561236916, COSV53525744; called by muse, mutect2, varscan2
- ERICH6 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 23/174 reads (13%) | catalogued as rs745449756, COSV55798827; called by muse, mutect2, varscan2
- ERVV-1 | c.836del p.P279Lfs*28 | Frame Shift Del (DEL) | VAF 68/467 reads (15%) | catalogued as rs752584775, COSV74083304; called by mutect2, varscan2
- ETFRF1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs568753362, COSV61357611; called by muse, mutect2, varscan2
- EXD3 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1373391245; called by muse, mutect2, varscan2
- EXTL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173785722; called by muse, mutect2
- FAM131C | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs549929286, COSV65153220; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 72/416 reads (17%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM53B | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766011933; called by muse, mutect2
- FAM83E | c.1411del p.R471Gfs*70 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs754029394, COSV52374478; called by mutect2, pindel, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FASN | c.1236del p.A413Hfs*39 | Frame Shift Del (DEL) | VAF 44/348 reads (13%) | catalogued as COSV60760319; called by mutect2, pindel, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 88/400 reads (22%) | catalogued as rs747011618; called by mutect2, varscan2
- FBLN2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1175308472, COSV55490831; called by muse, mutect2, varscan2
- FBXO38 | c.3131G>A p.R1044H (on ENST00000340253 / NM_205836.3; = p.R969H on NM_030793.5) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV57028193; called by muse, mutect2
- FBXW11 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV51608765; called by muse, mutect2
- FCN3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs746300270, COSV99585445; called by muse, mutect2, varscan2
- FCRL3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs529388680; called by muse, mutect2, varscan2
- FDPS | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV63115161; called by muse, mutect2, varscan2
- FGD6 | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269009624, COSV59696433; called by muse, mutect2, varscan2
- FGFR4 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52808538; called by muse, mutect2
- FGFR4 | c.2315G>T p.S772I | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV52810166; called by muse, mutect2, varscan2
- FIZ1 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.879); catalogued as rs1368647760; called by muse, mutect2, varscan2
- FLNA | c.7900del p.D2634Tfs*71 (on ENST00000369850 / NM_001110556.2; = p.D2626Tfs*71 on NM_001456.3) | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as COSV61046828; called by mutect2, varscan2
- FN1 | c.2738T>C p.L913P | Missense Mutation (SNP) | VAF 33/403 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1295128240; called by muse, mutect2
- FNDC3B | c.3165del p.T1056Pfs*7 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | catalogued as rs769012096; called by mutect2, pindel, varscan2
- FREM2 | c.8342G>A p.R2781H | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs756570666, COSV54841703; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMD4A | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as rs1454587930; called by muse, mutect2, varscan2
- GABBR1 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs765773664; called by muse, mutect2, varscan2
- GALC | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs755930402; called by muse, mutect2, varscan2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by muse, mutect2, varscan2
- GASK1B | c.755del p.G252Afs*23 | Frame Shift Del (DEL) | VAF 46/368 reads (13%) | catalogued as rs762957217; called by mutect2, pindel, varscan2
- GCK | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CD024177; called by muse, mutect2, varscan2
- GGA2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 41/239 reads (17%) | catalogued as rs774194384, COSV100564670; called by muse, mutect2, varscan2
- GH2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 173/483 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs751837455, COSV60427888; called by muse, mutect2, varscan2
- GLOD5 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as rs782746948, COSV57489125; called by muse, mutect2, varscan2
- GNA12 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.177); catalogued as rs150519840; called by muse, mutect2, varscan2
- GPR12 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1428897034; called by muse, mutect2, varscan2
- GPR152 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs916546709; called by muse, mutect2, varscan2
- GPR35 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs764719319; called by muse, mutect2, varscan2
- GRIN2C | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 98/514 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747113899; called by muse, mutect2, varscan2
- GRK6 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV62682863, COSV62684091; called by muse, mutect2, varscan2
- GRM4 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); catalogued as COSV65210788; called by muse, mutect2, varscan2
- GRWD1 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs765966446; called by mutect2, varscan2
- GSPT2 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.553); catalogued as COSV61214006; called by muse, mutect2, varscan2
- GTPBP4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs747080192; called by muse, mutect2, varscan2
- GZMM | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.153); catalogued as rs760924563, COSV52742316; called by muse, mutect2, varscan2
- HARS1 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs761949872, COSV56906227; called by muse, mutect2, varscan2
- HAUS5 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1485784128; called by muse, mutect2
- HBS1L | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs769187977; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 34/122 reads (28%) | catalogued as rs771658394; called by mutect2, varscan2
- HERC2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs766009752, COSV55348491; called by muse, mutect2, varscan2
- HHAT | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs368498838, COSV54798404, COSV54804822; called by muse, mutect2, varscan2
- HJURP | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs374823793; called by muse, mutect2, varscan2
- HNRNPUL2 | c.296del p.P99Lfs*43 | Frame Shift Del (DEL) | VAF 17/171 reads (10%) | catalogued as rs1388106459; called by mutect2, pindel
- HS6ST1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 151/531 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763039985; called by muse, mutect2, varscan2
- HSP90AA1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs778338593, COSV99355332; called by muse, mutect2, varscan2
- HSP90AB1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs1339214249, COSV62334155, COSV62335827; called by muse, mutect2, varscan2
- ICE2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as rs759819919; called by muse, mutect2, varscan2
- IFT22 | c.411G>A p.S137= | Splice Region (SNP) | VAF 81/254 reads (32%) | catalogued as rs758284945; called by muse, mutect2, varscan2
- IGF1R | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 104/484 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV51284745; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 38/280 reads (14%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | catalogued as rs748992699; called by mutect2, pindel, varscan2
- ILKAP | c.750del p.K250Nfs*5 | Frame Shift Del (DEL) | VAF 39/279 reads (14%) | catalogued as COSV54517280; called by mutect2, pindel, varscan2
- INPP4A | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777176771, COSV50785212; called by muse, mutect2, varscan2
- INPPL1 | c.3470del p.G1157Dfs*45 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs1565399032, COSV53356328, COSV99996061; called by mutect2, pindel, varscan2
- INTS2 | c.695del p.N232Mfs*25 | Frame Shift Del (DEL) | VAF 26/193 reads (13%) | catalogued as COSV52153211; called by mutect2, pindel, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQGAP3 | c.2542del p.H848Tfs*14 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | catalogued as COSV100752172; called by mutect2, pindel, varscan2
- ITGA8 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs1199269769; called by muse, varscan2
- ITGB2 | c.2015C>T p.P672L (on ENST00000302347; = p.P648L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs373963624, CM120021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR3 | c.1931C>A p.A644D | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100967069; called by muse, mutect2, varscan2
- JAG2 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762674945; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | catalogued as rs755650243; called by mutect2, varscan2
- KALRN | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs750456225, COSV53756036; called by muse, mutect2, varscan2
- KAT14 | c.1085del p.P362Hfs*17 | Frame Shift Del (DEL) | VAF 15/161 reads (9%) | catalogued as rs754512458; called by mutect2, pindel
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 61/313 reads (19%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNQ5 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs866886558, COSV59669652; called by muse, mutect2, varscan2
- KDM5A | c.3107G>A p.R1036H | Missense Mutation (SNP) | VAF 40/403 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.099); catalogued as rs746956221, COSV66996400; called by muse, mutect2
- KEAP1 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261404; called by muse, mutect2
- KHNYN | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774390018, COSV52159433; called by muse, mutect2, varscan2
- KIAA0100 | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 33/517 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV101197316; called by muse, mutect2
- KIAA1217 | c.463del p.D155Mfs*19 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs1264299382; called by mutect2, pindel, varscan2
- KIAA1549 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs781559902; called by muse, mutect2, varscan2
- KIF12 | c.1885C>T p.R629* (on ENST00000640217; = p.R491* on NM_138424.1) | Nonsense Mutation (SNP) | VAF 33/196 reads (17%) | catalogued as rs370128201, COSV65116663; called by muse, mutect2, varscan2
- KIF16B | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs180803641, COSV61716498; called by muse, mutect2, varscan2
- KIF1C | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs142944883; called by muse, mutect2, varscan2
- KIF24 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369938636; called by muse, mutect2, varscan2
- KIF26B | c.5021T>C p.V1674A | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs200279444; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KRT76 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372674456; called by muse, varscan2
- KRT81 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 198/568 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs773592999; called by muse, mutect2, varscan2
- LARS1 | c.3493G>A p.V1165M (on ENST00000394434 / NM_020117.11; = p.V1138M on NM_016460.3) | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1266297621; called by muse, mutect2
- LCT | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs775399160, COSV51547775, COSV51557941; called by muse, mutect2
- LOXHD1 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs112463030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP4 | c.3119G>A p.G1040D | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV66135473; called by muse, mutect2, varscan2
- LRRC9 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1221637773; called by muse, mutect2, varscan2
- LRRIQ1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 124/358 reads (35%) | catalogued as rs374902495; called by muse, mutect2, varscan2
- LRRN3 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs527885827, COSV57824246; called by muse, mutect2, varscan2
- LRRTM1 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54440582; called by muse, mutect2, varscan2
- MADD | c.4922C>T p.P1641L | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); catalogued as rs755722711; called by muse, mutect2, varscan2
- MAGEL2 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.1); catalogued as COSV58569159; called by muse, mutect2, varscan2
- MALRD1 | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs908498078; called by muse, mutect2, varscan2
- MAMDC4 | c.2534del p.P845Qfs*31 (on ENST00000445819; = p.P766Qfs*31 on NM_206920.3) | Frame Shift Del (DEL) | VAF 99/345 reads (29%) | catalogued as rs757170524; called by mutect2, pindel, varscan2
- MAP4K1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67710026; called by muse, mutect2, varscan2
- MAPK15 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as rs782786398; called by muse, mutect2, varscan2
- MAPK3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99531812; called by muse, mutect2
- MAPKAPK3 | c.915C>T p.N305= | Splice Region (SNP) | VAF 46/202 reads (23%) | catalogued as rs957985236; called by muse, mutect2, varscan2
- MAST3 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 70/418 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1452121136; called by muse, mutect2, varscan2
- MCHR2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 45/301 reads (15%) | catalogued as rs748678430, COSV56006823; called by muse, mutect2, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 26/124 reads (21%) | catalogued as rs772983071; called by mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAM | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1181164759; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 27/130 reads (21%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MLH1 | c.588+1G>A p.X196_splice | Splice Site (SNP) | VAF 105/309 reads (34%) | catalogued as CD056171, CS065593; called by muse, mutect2, varscan2
- MRGPRG | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1286401856; called by muse, mutect2
- MRTFA | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs762204984, COSV62935914; called by muse, mutect2, varscan2
- MYH2 | c.5708G>A p.R1903H | Missense Mutation (SNP) | VAF 90/407 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770302436, COSV55432703; called by muse, mutect2, varscan2
- MYO15A | c.3610-8T>A | Splice Region (SNP) | VAF 60/422 reads (14%) | catalogued as rs765041022, COSV52751650; called by muse, mutect2, varscan2
- MYO1D | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433956761, COSV100554336; called by muse, mutect2, varscan2
- MYO3B | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371669866, COSV58700128; called by muse, mutect2, varscan2
- MYO5B | c.4528C>T p.R1510W | Missense Mutation (SNP) | VAF 160/457 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs192784103; called by muse, mutect2, varscan2
- MYO7B | c.3631G>A p.V1211I | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs780525594, COSV67348317; called by muse, mutect2, varscan2
- MYOM2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs144139938; called by muse, mutect2, varscan2
- NAGK | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs1169305196; called by muse, mutect2, varscan2
- NCAM2 | c.1203del p.K402Sfs*19 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV99525585; called by mutect2, pindel, varscan2
- NCOR2 | c.3904dup p.H1302Pfs*2 | Frame Shift Ins (INS) | VAF 22/172 reads (13%) | catalogued as rs768164546; called by mutect2, varscan2
- NELFE | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752846295; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs759081520; called by mutect2, varscan2
- NFATC2 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.522); catalogued as rs1406603021; called by muse, mutect2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 49/291 reads (17%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 15/440 reads (3%) | catalogued as COSV53063202; called by muse, mutect2
- NOX4 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779309020, COSV99629197; called by muse, mutect2, varscan2
- NOX5 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs1214209867; called by muse, mutect2, varscan2
- NPAS2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs183671025, COSV100177277; called by muse, mutect2, varscan2
- NPHS1 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs772278981, COSV100800301; called by muse, mutect2, varscan2
- NR1D1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753922085; called by muse, mutect2, varscan2
- NR1H3 | c.19del p.A7Pfs*107 | Frame Shift Del (DEL) | VAF 50/366 reads (14%) | catalogued as rs1199779898; called by mutect2, pindel, varscan2
- NRN1L | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142084682; called by muse, varscan2
- NRXN3 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55325456; called by muse, mutect2, varscan2
- NSMCE1 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs770865488; called by muse, mutect2, varscan2
- NTAQ1 | c.50dup p.R18Afs*12 | Frame Shift Ins (INS) | VAF 31/213 reads (15%) | catalogued as rs1340136345; called by mutect2, varscan2
- NTN5 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1166689997, COSV54308449; called by muse, mutect2, varscan2
- NTRK1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs537948663, COSV62324388, COSV62327673; called by muse, mutect2, varscan2
- NYAP2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349573850, COSV55998979; called by muse, mutect2, varscan2
- NYAP2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361526299, COSV56007357; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs762005098; called by mutect2, varscan2
- OOEP | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV64858968; called by muse, mutect2, varscan2
- OR10H5 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.337); catalogued as rs575365825, COSV58277696; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 44/314 reads (14%) | catalogued as rs761899382; called by mutect2, varscan2
- OSBPL1A | c.1738C>A p.L580I (on ENST00000319481 / NM_080597.4; = p.L67I on NM_018030.4) | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); catalogued as COSV100110843; called by muse, mutect2, varscan2
- PAPLN | c.799C>T p.R267* (on ENST00000554301; = p.R240* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as rs199674160; called by muse, mutect2
- PAPPA | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867106756, COSV100073308; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 78/250 reads (31%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 161/416 reads (39%) | catalogued as CM011452; called by pindel, varscan2
- PCDH11X | c.2877G>T p.K959N | Missense Mutation (SNP) | VAF 86/594 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100011175; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 41/183 reads (22%) | catalogued as rs772305388; called by mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs1405726136; called by mutect2, pindel, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs759495724; called by mutect2, varscan2
- PHF10 | c.1448dup p.T484Nfs*18 | Frame Shift Ins (INS) | VAF 31/114 reads (27%) | catalogued as rs754137375; called by mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF8 | c.1688C>T p.T563I (on ENST00000357988 / NM_001184896.1; = p.T527I on NM_015107.3) | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1557101996, COSV57682138; called by muse, mutect2, varscan2
- PI4KA | c.4372del p.L1458Cfs*29 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | catalogued as rs751598418; called by mutect2, pindel, varscan2
- PI4KB | c.2222G>A p.R741Q (on ENST00000368873 / NM_001369623.1; = p.R753Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV55022726; called by muse, mutect2, varscan2
- PIGQ | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs751055581; called by muse, mutect2, varscan2
- PLEKHM3 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101216625; called by muse, mutect2, varscan2
- PLIN4 | c.65C>T p.A22V (on ENST00000301286; = p.A37V on NM_001367868.2) | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs866697834; called by muse, mutect2, varscan2
- PLXNA3 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782380731; called by muse, mutect2, varscan2
- PLXNB2 | c.1287C>A p.Y429* | Nonsense Mutation (SNP) | VAF 27/181 reads (15%) | catalogued as COSV63781944; called by muse, mutect2, varscan2
- PLXND1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.412); catalogued as rs781768858, COSV60710422; called by muse, varscan2
- POLRMT | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV73933257; called by muse, mutect2
- POMT1 | c.540-2A>G p.X180_splice | Splice Site (SNP) | VAF 24/830 reads (3%) | catalogued as rs947926307; called by muse, mutect2
- PPP1R3A | c.2975G>A p.C992Y | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99493019; called by muse, mutect2, varscan2
- PPP1R3G | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs1349606532, COSV68161409; called by muse, mutect2, varscan2
- PRAMEF18 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 89/895 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as rs1316874811; called by muse, mutect2, varscan2
- PRCC | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54855854; called by muse, mutect2, varscan2
- PREP | c.1162A>G p.I388V (on ENST00000369110; = p.I454V on NM_002726.5) | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs531198200; called by muse, mutect2, varscan2
- PRMT1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775323970; called by muse, mutect2
- PROSER2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as rs760275871; called by muse, mutect2, varscan2
- PRPF6 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 191/621 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); catalogued as COSV99413148; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 19/165 reads (12%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PTCH1 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 31/443 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs762152128; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 127/220 reads (58%) | catalogued as rs146650273; called by pindel, varscan2
- PTPN1 | c.1130dup p.S378Kfs*61 | Frame Shift Ins (INS) | VAF 11/94 reads (12%) | catalogued as rs1175258966; called by mutect2, pindel, varscan2
- PTPN23 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167043593; called by muse, mutect2, varscan2
- PTPRF | c.4399C>T p.R1467C | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778315843, COSV63448765; called by muse, mutect2, varscan2
- PTPRM | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as rs770279168, COSV59848745; called by muse, mutect2, varscan2
- PUSL1 | c.633del p.E212Rfs*26 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs764750132; called by mutect2, pindel, varscan2
- PXDN | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770394672, COSV53227060; called by muse, mutect2, varscan2
- PZP | c.3953_3954del p.Y1318Cfs*70 | Frame Shift Del (DEL) | VAF 48/242 reads (20%) | catalogued as rs1334080876; called by pindel, varscan2
- RAB13 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs202131118, COSV55132158; called by muse, mutect2, varscan2
- RAB15 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs750200493; called by muse, varscan2
- RAP1GAP2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1412068087, COSV104368412; called by muse, mutect2, varscan2
- RASD1 | c.540_542del p.K180del | In Frame Del (DEL) | VAF 43/137 reads (31%) | catalogued as rs765782505; called by pindel, varscan2
- RASSF2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1482284481, COSV101040888; called by muse, mutect2, varscan2
- RBM15 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs751646444; called by muse, mutect2
- RBM33 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775429594; called by muse, mutect2, varscan2
- RBP3 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs781938600; called by muse, mutect2
- REV1 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs761325438; called by muse, mutect2, varscan2
- RFX2 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 111/335 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs769822837; called by muse, mutect2, varscan2
- RNF223 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1320328779; called by muse, mutect2
- RPP25L | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs989207453, COSV99426715, COSV99427199; called by muse, mutect2
- RPS6KA2 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs778197293, COSV104378122, COSV99692015; called by muse, mutect2, varscan2
- RTKN | c.1612del p.L538Sfs*117 (on ENST00000272430 / NM_001015055.2; = p.L525Sfs*117 on NM_033046.2) | Frame Shift Del (DEL) | VAF 35/248 reads (14%) | catalogued as rs1054567891; called by mutect2, pindel, varscan2
- RTP5 | c.890G>A p.C297Y | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs767949434; called by muse, mutect2, varscan2
- RYR1 | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200698933, COSV62091481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.9905del p.P3302Hfs*19 | Frame Shift Del (DEL) | VAF 52/382 reads (14%) | catalogued as rs749656679; called by mutect2, pindel, varscan2
- S1PR3 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100822450; called by muse, mutect2
- SCAMP1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs747133518; called by muse, mutect2
- SDK1 | c.1610del p.G537Vfs*26 | Frame Shift Del (DEL) | VAF 9/94 reads (10%) | catalogued as COSV67370898; called by mutect2, pindel, varscan2
- SDK1 | c.5450C>T p.T1817M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs746369052, COSV67362881; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 66/192 reads (34%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3B | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553706360; called by muse, mutect2
- SERTAD2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs199521891, COSV100512216; called by muse, mutect2, varscan2
- SETBP1 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1356624472; called by muse, mutect2, varscan2
- SF3B2 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs747635710, COSV59427767; called by muse, mutect2
- SFSWAP | c.527del p.N176Mfs*6 | Frame Shift Del (DEL) | VAF 81/231 reads (35%) | catalogued as rs1566002834; called by mutect2, pindel, varscan2
- SFTPB | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1001637675; called by muse, mutect2, varscan2
- SH3KBP1 | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV101115794; called by muse, mutect2, varscan2
- SH3TC2 | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 51/491 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141712019, COSV60466647; called by muse, mutect2, varscan2
- SHB | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1313047032, COSV66629256; called by muse, mutect2, varscan2
- SHB | c.124del p.Q42Rfs*199 | Frame Shift Del (DEL) | VAF 42/129 reads (33%) | catalogued as rs778597364; called by mutect2, pindel, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 57/320 reads (18%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC17A3 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1018399218; called by muse, mutect2, varscan2
- SLC1A1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 84/448 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as rs201587651; called by muse, mutect2, varscan2
- SLC1A6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs781551972, COSV55671318, COSV55675054; called by muse, mutect2, varscan2
- SLC25A45 | c.330del p.F111Sfs*60 | Frame Shift Del (DEL) | VAF 38/285 reads (13%) | catalogued as rs774930220; called by mutect2, pindel, varscan2
- SLC26A1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs558027930, COSV56104355; called by muse, mutect2, varscan2
- SLC27A5 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV99564345; called by muse, mutect2, varscan2
- SLC38A2 | c.1180-5del | Splice Region (DEL) | VAF 31/139 reads (22%) | catalogued as rs755947254; called by mutect2, varscan2
- SLC6A6 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs770761525, COSV100692631; called by muse, mutect2, varscan2
- SLC9A2 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs774494897, COSV52132917; called by muse, mutect2, varscan2
- SLIT2 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1324795982, COSV99879585; called by muse, mutect2, varscan2
- SMCHD1 | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs1188737588; called by muse, mutect2, varscan2
- SMOX | c.908del p.G303Afs*20 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs746816975, COSV53864789; called by mutect2, pindel, varscan2
- SPATA22 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs80253914; called by muse, mutect2, varscan2
- SPATA6 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142638384; called by muse, mutect2, varscan2
- SPEM2 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs113604978, COSV60366859; called by muse, mutect2, varscan2
- SPNS1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs774014230; called by muse, mutect2, varscan2
- SPTAN1 | c.6482G>A p.R2161H | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs200834733, COSV63987286; called by muse, mutect2, varscan2
- SRGAP2 | c.2284G>A p.D762N (on ENST00000624873 / NM_001170637.4; = p.D763N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs781996641; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 32/243 reads (13%) | PolyPhen probably damaging (0.959); catalogued as rs763867212, COSV59561902; called by muse, mutect2, varscan2
- STAG3 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760438992; called by muse, mutect2, varscan2
- STK16 | c.859_861del p.L287del | In Frame Del (DEL) | VAF 24/105 reads (23%) | catalogued as rs1172049307; called by pindel, varscan2
- SZT2 | c.3268G>A p.G1090S (on ENST00000634258 / NM_001365999.1; = p.G1033S on NM_015284.4) | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1409656203; called by muse, mutect2, varscan2
- TARBP2 | c.776G>A p.R259Q (on ENST00000266987 / NM_134323.2; = p.R238Q on NM_004178.4) | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs1445111857; called by muse, mutect2, varscan2
- TARS2 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs192883326; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D26 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1326078802; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 41/292 reads (14%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TDRD6 | c.3433A>G p.N1145D | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs1251569677; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 34/158 reads (22%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR2 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849996; called by muse, mutect2, varscan2
- TEKT4 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 16/531 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as rs1553394645; called by muse, mutect2
- TERT | c.2580C>T p.D860= | Splice Region (SNP) | VAF 61/191 reads (32%) | catalogued as rs751752830, COSV57222937; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TEX15 | c.7863T>A p.N2621K (on ENST00000256246; = p.N3004K on NM_001350162.2) | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV56355716; called by muse, mutect2, varscan2
- THBS3 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755795631; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | catalogued as rs746975641; called by mutect2, varscan2
- THOC2 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55547602; called by muse, mutect2, varscan2
- THUMPD1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV67263204; called by muse, mutect2, varscan2
- TIE1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs11545380, COSV65251541; called by muse, mutect2, varscan2
- TJP1 | c.54A>G p.I18M | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567054272; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMC3 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV100845869; called by muse, mutect2
- TMCC2 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as rs1300001544, COSV100319563; called by muse, mutect2
- TMCC3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs781764514, COSV54152619, COSV54153235; called by muse, mutect2, varscan2
- TMEM184A | c.997_999del p.K333del | In Frame Del (DEL) | VAF 124/323 reads (38%) | catalogued as rs548246825; called by pindel, varscan2
- TMEM198 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs763015024, COSV54717319; called by muse, mutect2, varscan2
- TMEM245 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 42/268 reads (16%) | catalogued as COSV101002346; called by muse, mutect2, varscan2
- TMEM249 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs529029687, COSV59398609; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 38/174 reads (22%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TNFRSF10D | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100441805, COSV100441887; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4552A>C p.T1518P | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs758122255, COSV64100288; called by muse, mutect2, varscan2
- TNPO3 | c.2541dup p.Y848Lfs*8 | Frame Shift Ins (INS) | VAF 42/196 reads (21%) | catalogued as rs761308428; called by mutect2, varscan2
- TNR | c.2399del p.P800Qfs*18 | Frame Shift Del (DEL) | VAF 18/137 reads (13%) | catalogued as COSV54887859; called by mutect2, pindel, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 44/209 reads (21%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS3 | c.2358del p.Q787Sfs*33 | Frame Shift Del (DEL) | VAF 37/302 reads (12%) | catalogued as COSV60787512; called by mutect2, pindel, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TPBG | c.129_131del p.S44del | In Frame Del (DEL) | VAF 22/198 reads (11%) | catalogued as rs747096492; called by pindel, varscan2
- TRAV38-2DV8 | c.316del p.D106Mfs*? | Frame Shift Del (DEL) | VAF 19/129 reads (15%) | catalogued as rs1365673856; called by mutect2, pindel, varscan2
- TRIM3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs750980669; called by muse, mutect2, varscan2
- TRPC5 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1410735076, COSV53305486; called by muse, mutect2, varscan2
- TRPC6 | c.2379del p.G794Vfs*8 | Frame Shift Del (DEL) | VAF 29/251 reads (12%) | catalogued as rs757567055; called by mutect2, pindel, varscan2
- TRPC7 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 55/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61460813; called by muse, mutect2, varscan2
- TRPV4 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1227793261, COSV99924534; called by muse, mutect2, varscan2
- TSC2 | c.3871G>A p.V1291I | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201135184; ClinVar: not provided / likely benign / benign; called by muse, mutect2, varscan2
- TSPAN6 | c.305del p.L102Wfs*9 | Frame Shift Del (DEL) | VAF 31/204 reads (15%) | catalogued as rs757907711; called by mutect2, pindel, varscan2
- TSPYL5 | c.223del p.E75Rfs*89 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as COSV59071686; called by mutect2, pindel, varscan2
- TTC28 | c.5282G>A p.R1761H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs748910267, COSV67414612; called by muse, mutect2, varscan2
- TTC36 | c.175del p.V59* | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as COSV57097020; called by mutect2, pindel, varscan2
- TTN | c.6358C>T p.R2120W (on ENST00000591111; = p.R2074W on NM_003319.4) | Missense Mutation (SNP) | VAF 159/407 reads (39%) | PolyPhen probably damaging (0.96); catalogued as rs116158152, COSV59904099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.7); catalogued as rs138384157, COSV68028168; called by muse, mutect2
- UBE4B | c.3139C>T p.R1047* (on ENST00000343090 / NM_001105562.3; = p.R918* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | catalogued as COSV53527127; called by muse, mutect2, varscan2
- USB1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs1038958942; called by muse, mutect2
- USP44 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755726154; called by muse, mutect2, varscan2
- UTRN | c.6080G>A p.S2027N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV62330146; called by muse, mutect2, varscan2
- VCAN | c.1010del p.P337Lfs*20 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as COSV54109476; called by mutect2, pindel, varscan2
- VEGFC | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54598574; called by muse, mutect2, varscan2
- VWA5B1 | c.3287C>T p.P1096L (on ENST00000375079; = p.P1091L on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs767054970; called by muse, mutect2, varscan2
- VWA5B2 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs570895262, COSV56611975; called by muse, mutect2, varscan2
- VWF | c.2597C>T p.T866M | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1391742837; called by muse, mutect2, varscan2
- WAS | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as rs782802310, COSV64997375; called by muse, mutect2
- WDR83 | c.365_366del p.T122Sfs*8 | Frame Shift Del (DEL) | VAF 34/254 reads (13%) | catalogued as rs770548568; called by pindel, varscan2
- YBX2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs752018878; called by muse, mutect2, varscan2
- ZBED6 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1336343951; called by muse, mutect2
- ZCCHC14 | c.2187del p.S730Afs*73 (on ENST00000268616; = p.S867Afs*73 on NM_015144.3) | Frame Shift Del (DEL) | VAF 40/300 reads (13%) | catalogued as COSV99234343; called by pindel, varscan2
- ZDBF2 | c.5069G>A p.R1690Q | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs757506025, COSV65622904; called by muse, mutect2, varscan2
- ZDHHC12 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs151171283; called by muse, mutect2, varscan2
- ZDHHC16 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs778141290, COSV100512653; called by muse, mutect2, varscan2
- ZFHX2 | c.7603A>G p.T2535A | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs1476532199, COSV70219923; called by muse, mutect2, varscan2
- ZMYM1 | c.1516dup p.T506Nfs*9 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs772297962; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF131 | c.980T>A p.I327N (on ENST00000509156 / NM_001330707.2; = p.I293N on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104405958; called by muse, mutect2, varscan2
- ZNF208 | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.506); catalogued as COSV68099617; called by muse, mutect2
- ZNF280C | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1003362143, COSV63968674; called by muse, mutect2, varscan2
- ZNF282 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1220675786, COSV100021413; called by muse, mutect2
- ZNF317 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV56109018; called by muse, mutect2, varscan2
- ZNF423 | c.3739G>A p.V1247I (on ENST00000563137 / NM_001379286.1; = p.V1239I on NM_015069.4) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as rs911470655, COSV52186843; called by muse, mutect2
- ZNF526 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as rs775804386, COSV99725537; called by muse, mutect2, varscan2
- ZNF541 | c.3598G>A p.V1200I | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs768036432; called by muse, mutect2, varscan2
- ZNF77 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs200003978; called by muse, mutect2, varscan2
- ZNF831 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs768730442, COSV64043250; called by muse, mutect2, varscan2
- ZRANB1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV62843252; called by muse, mutect2, varscan2
- ZSCAN12 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs759092710, COSV63010731; called by muse, mutect2
- ABCC1 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCG2 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCG4 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ABTB2 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AC245033.1 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 188/572 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ACKR2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ACOX2 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 15/328 reads (5%) | called by muse, mutect2
- ACRV1 | c.30_31del p.Y11Sfs*13 | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | called by mutect2, pindel, varscan2
- ACSL4 | c.829T>C p.Y277H (on ENST00000340800 / NM_022977.2; = p.Y236H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM11 | c.1040del p.G347Afs*11 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- ADAMTSL1 | c.3464del p.G1155Efs*42 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- ADARB2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2
- ADAT1 | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY8 | c.2753A>G p.Q918R | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADIPOR1 | c.452del p.L151Wfs*4 | Frame Shift Del (DEL) | VAF 47/131 reads (36%) | called by mutect2, pindel, varscan2
- ADK | c.312del p.F104Lfs*6 (on ENST00000286621; = p.F87Lfs*6 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 67/390 reads (17%) | called by mutect2, varscan2
- AGER | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGFG1 | c.317A>C p.D106A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- AHDC1 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHNAK | c.8561A>G p.D2854G | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); called by muse, mutect2
- AIFM1 | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 122/542 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, varscan2
- AKAP1 | c.341C>G p.T114S | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP14 | c.230del p.K77Rfs*23 | Frame Shift Del (DEL) | VAF 86/323 reads (27%) | called by mutect2, pindel, varscan2
- AMBN | c.799-1G>A p.X267_splice | Splice Site (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- ANK1 | c.1701del p.N568Mfs*3 | Frame Shift Del (DEL) | VAF 45/307 reads (15%) | called by mutect2, pindel, varscan2
- ANKRD50 | c.3855del p.A1286Rfs*12 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | called by mutect2, pindel, varscan2
- AP4B1 | c.618-7dup | Splice Region (INS) | VAF 14/128 reads (11%) | called by mutect2, pindel, varscan2
- APPL2 | c.1221del p.K407Nfs*11 | Frame Shift Del (DEL) | VAF 31/203 reads (15%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.1475del p.N492Mfs*28 | Frame Shift Del (DEL) | VAF 76/234 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP27 | c.739del p.L247Ffs*53 | Frame Shift Del (DEL) | VAF 59/217 reads (27%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.2650C>A p.L884M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 10/111 reads (9%) | called by mutect2, pindel
- ARHGEF5 | c.4540del p.Q1514Rfs*24 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel, varscan2
- ARID1A | c.3524del p.P1175Hfs*5 | Frame Shift Del (DEL) | VAF 22/235 reads (9%) | called by mutect2, pindel
- ARID1A | c.4689del p.M1564* | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 49/328 reads (15%) | called by mutect2, pindel, varscan2
- ARL10 | c.388_389insT p.G130Vfs*28 | Frame Shift Ins (INS) | VAF 15/100 reads (15%) | called by pindel, varscan2
- ASCL1 | c.698_700del p.T233del | In Frame Del (DEL) | VAF 42/310 reads (14%) | called by mutect2, pindel, varscan2
- ASIC3 | c.444dup p.L149Tfs*11 | Frame Shift Ins (INS) | VAF 22/153 reads (14%) | called by mutect2, pindel, varscan2
- ASIC4 | c.649dup p.A217Gfs*28 | Frame Shift Ins (INS) | VAF 25/190 reads (13%) | called by mutect2, pindel, varscan2
- ATG2A | c.5343del p.L1782Cfs*101 | Frame Shift Del (DEL) | VAF 101/358 reads (28%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.1222+2T>C p.X408_splice | Splice Site (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2
- B4GALNT4 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- B4GALT1 | c.893T>A p.L298Q | Missense Mutation (SNP) | VAF 75/416 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- B4GALT4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- BAZ2B | c.5923del p.C1975Vfs*13 | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | called by mutect2, pindel, varscan2
- BCL6 | c.957del p.N320Mfs*4 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- BMP10 | c.796A>T p.R266W | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- BMP15 | c.80_82del p.E27del | In Frame Del (DEL) | VAF 94/271 reads (35%) | called by mutect2, pindel, varscan2
- BTBD7 | c.2303del p.P768Qfs*53 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | called by pindel, varscan2
- C1R | c.341del p.P114Rfs*15 (on ENST00000536053 / NM_001354346.2; = p.P100Rfs*15 on NM_001733.7) | Frame Shift Del (DEL) | VAF 43/165 reads (26%) | called by mutect2, pindel, varscan2
- C1RL | c.239G>T p.R80M | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- C1orf112 | c.2505G>T p.M835I | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2
- C4B | c.3809T>C p.L1270P | Missense Mutation (SNP) | VAF 40/1154 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C6 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf132 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- CAMK4 | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CAMK4 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CAMSAP3 | c.3001del p.R1001Gfs*41 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- CASD1 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERD | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCL2 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2
- CCM2L | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCR1 | c.747del p.L250Sfs*8 | Frame Shift Del (DEL) | VAF 17/135 reads (13%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4408T>C p.S1470P | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CDON | c.1756C>A p.P586T | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM5 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- CEP162 | c.405del p.F135Lfs*8 | Frame Shift Del (DEL) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- CEP57 | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- CFAP44 | c.2906T>C p.L969S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CHAD | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHRNA10 | c.502T>G p.C168G | Missense Mutation (SNP) | VAF 143/459 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHST1 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CLASP1 | c.4583G>T p.S1528I | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CLIP1 | c.2500A>G p.N834D (on ENST00000620786 / NM_001247997.1; = p.N823D on NM_002956.2) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLNS1A | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A1 | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- COL6A6 | c.2379del p.F793Lfs*16 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- COL8A1 | c.404del p.P135Lfs*119 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- COMT | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- COQ9 | c.240del p.R81Gfs*24 | Frame Shift Del (DEL) | VAF 74/499 reads (15%) | called by mutect2, varscan2
- COX11 | c.786del p.F262Lfs*20 | Frame Shift Del (DEL) | VAF 33/227 reads (15%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.162G>A p.W54* (on ENST00000651564; = p.W7* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- CPPED1 | c.942del p.K314Nfs*30 | Frame Shift Del (DEL) | VAF 43/205 reads (21%) | called by mutect2, pindel, varscan2
- CROCC2 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CRYBG3 | c.6953C>T p.A2318V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CSMD3 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CTDP1 | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 71/430 reads (17%) | called by muse, mutect2, varscan2
- CTHRC1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CTSV | c.274A>C p.M92L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CUBN | c.8997_8998del p.C2999Wfs*3 | Frame Shift Del (DEL) | VAF 80/659 reads (12%) | called by pindel, varscan2
- CUX1 | c.2376del p.L794Wfs*14 | Frame Shift Del (DEL) | VAF 79/259 reads (31%) | called by mutect2, pindel, varscan2
- CWC27 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, varscan2
- CYB5RL | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 155/471 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, varscan2
- CYLD | c.2305dup p.I769Nfs*14 | Frame Shift Ins (INS) | VAF 20/128 reads (16%) | called by mutect2, varscan2
- DCLRE1C | c.109+2T>C p.X37_splice | Splice Site (SNP) | VAF 98/274 reads (36%) | called by muse, mutect2, varscan2
- DDB1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDR2 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND4B | c.3263del p.P1088Qfs*42 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- DENND4C | c.905del p.M302Rfs*75 | Frame Shift Del (DEL) | VAF 70/284 reads (25%) | called by mutect2, pindel, varscan2
- DEPDC1B | c.234del p.K78Nfs*3 | Frame Shift Del (DEL) | VAF 109/393 reads (28%) | called by mutect2, pindel, varscan2
- DMRT1 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 176/505 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.9500C>T p.T3167I | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNM2 | c.2348C>T p.A783V (on ENST00000355667 / NM_001005360.3; = p.A779V on NM_004945.3) | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- DOCK11 | c.2417G>A p.G806D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DOCK6 | c.3258C>A p.S1086R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2
- DST | c.19484T>C p.L6495P (on ENST00000361203 / NM_001374722.1; = p.L4192P on NM_015548.5) | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUS3L | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DVL1 | c.1309C>T p.L437F (on ENST00000378888 / NM_001330311.2; = p.L412F on NM_004421.3) | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EBF3 | c.1147dup p.A383Gfs*107 (on ENST00000355311 / NM_001375392.1; = p.A374Gfs*107 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/148 reads (11%) | called by pindel, varscan2
- EEF1A1 | c.899_902del p.S300Kfs*44 | Frame Shift Del (DEL) | VAF 52/213 reads (24%) | called by mutect2, pindel, varscan2
- EEF1G | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 30/638 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- EIF5B | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELP5 | c.728_729del p.I243Tfs*12 | Frame Shift Del (DEL) | VAF 72/386 reads (19%) | called by pindel, varscan2
- EMILIN1 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPB42 | c.1585A>G p.K529E (on ENST00000441366 / NM_001114134.2; = p.K559E on NM_000119.3) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- EPPK1 | c.233A>G p.Q78R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERRFI1 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ETF1 | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EWSR1 | c.1860del p.P622Lfs*4 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- EXD3 | c.144del p.F49Lfs*53 | Frame Shift Del (DEL) | VAF 19/159 reads (12%) | called by mutect2, pindel, varscan2
- EXO1 | c.2190dup p.D731Rfs*13 | Frame Shift Ins (INS) | VAF 28/212 reads (13%) | called by mutect2, varscan2
- EXT1 | c.690del p.F230Lfs*22 | Frame Shift Del (DEL) | VAF 37/423 reads (9%) | called by mutect2, pindel
- EYS | c.3734G>A p.C1245Y | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- FAAP100 | c.641dup p.S215Lfs*18 | Frame Shift Ins (INS) | VAF 47/370 reads (13%) | called by mutect2, pindel, varscan2
- FAM114A1 | c.959del p.L320* | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- FAM124A | c.1566G>T p.Q522H (on ENST00000322475 / NM_001242312.2; = p.Q558H on NM_145019.4) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- FAM149A | c.1148C>A p.P383H (on ENST00000356371 / NM_001367768.2; = p.P92H on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- FAM151B | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- FAM167A | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- FAM20C | c.1594dup p.D532Gfs*41 | Frame Shift Ins (INS) | VAF 45/320 reads (14%) | called by mutect2, pindel, varscan2
- FAM78A | c.247_249del p.K83del | In Frame Del (DEL) | VAF 16/90 reads (18%) | called by pindel, varscan2
- FAM83D | c.1249T>C p.C417R | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FANCM | c.5091_5093del p.K1697del | In Frame Del (DEL) | VAF 83/258 reads (32%) | called by pindel, varscan2
- FAT4 | c.10522A>T p.N3508Y | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBRSL1 | c.2035del p.L679* | Frame Shift Del (DEL) | VAF 40/202 reads (20%) | called by mutect2, pindel, varscan2
- FBXL18 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO10 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FEZF1 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FFAR3 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, varscan2
- FHDC1 | c.1717del p.R573Gfs*11 | Frame Shift Del (DEL) | VAF 48/285 reads (17%) | called by mutect2, pindel, varscan2
- FNDC3A | c.3520G>T p.A1174S (on ENST00000492622 / NM_001079673.2; = p.A1118S on NM_014923.5) | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FOXG1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FOXN4 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2
- FRMPD3 | c.4286G>A p.S1429N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GAL3ST2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 74/512 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GALNT11 | c.45del p.F15Lfs*19 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | called by mutect2, pindel, varscan2
- GANC | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 15/212 reads (7%) | PolyPhen benign (0.017); called by muse, mutect2
- GAREM2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- GBX2 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GFM1 | c.2238del p.G747Efs*17 | Frame Shift Del (DEL) | VAF 65/288 reads (23%) | called by mutect2, varscan2
- GFRA2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI3 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- GNAI1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GOLGA2 | c.1510del p.E504Sfs*42 | Frame Shift Del (DEL) | VAF 57/377 reads (15%) | called by mutect2, pindel, varscan2
- GPR37 | c.1706A>C p.E569A | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- GPR39 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN3B | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- GRINA | c.765_767del p.I255del | In Frame Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- GSPT2 | c.1148dup p.D384Gfs*16 | Frame Shift Ins (INS) | VAF 30/223 reads (13%) | called by mutect2, pindel, varscan2
- GSX1 | c.213del p.P73Rfs*88 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- GTPBP2 | c.325A>G p.N109D | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.357); called by muse, mutect2
- GUCY2D | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- GYPA | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- H1-8 | c.361del p.A121Pfs*7 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel, varscan2
- HDAC10 | c.704del p.N235Tfs*82 | Frame Shift Del (DEL) | VAF 63/334 reads (19%) | called by mutect2, pindel, varscan2
- HELZ2 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- HIGD1B | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLX | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- HMG20B | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 118/337 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- HMGCLL1 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMX1 | c.300del p.G101Vfs*124 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- HS3ST6 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSD11B1L | c.845dup p.N282Kfs*19 | Frame Shift Ins (INS) | VAF 56/421 reads (13%) | called by mutect2, pindel, varscan2
- HSPG2 | c.3800G>A p.S1267N | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- IFNGR2 | c.520dup p.C174Lfs*28 | Frame Shift Ins (INS) | VAF 66/363 reads (18%) | called by mutect2, varscan2
- IFT140 | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- IGF2BP3 | c.1657del p.I553Ffs*5 | Frame Shift Del (DEL) | VAF 54/207 reads (26%) | called by mutect2, pindel, varscan2
- INCENP | c.1732C>A p.L578I (on ENST00000394818 / NM_001040694.2; = p.L574I on NM_020238.3) | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- INHBB | c.1109_1111del p.S370del | In Frame Del (DEL) | VAF 78/279 reads (28%) | called by mutect2, pindel, varscan2
- INPP5D | c.2437G>A p.E813K (on ENST00000445964 / NM_001017915.3; = p.E812K on NM_005541.5) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INPPL1 | c.1322del p.N441Tfs*2 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- ITGA7 | c.803-5dup | Splice Region (INS) | VAF 41/259 reads (16%) | called by mutect2, pindel, varscan2
- IZUMO1 | c.885del p.L296Cfs*2 | Frame Shift Del (DEL) | VAF 36/209 reads (17%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, varscan2
- JMJD1C | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KAT6A | c.4244T>C p.I1415T | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.124); called by muse, mutect2
- KCNH1 | c.2615C>T p.A872V (on ENST00000271751 / NM_172362.3; = p.A845V on NM_002238.4) | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK10 | c.9dup p.L4Sfs*26 | Frame Shift Ins (INS) | VAF 62/247 reads (25%) | called by mutect2, pindel, varscan2
- KCNT1 | c.2889C>A p.S963= (on ENST00000488444; = p.S982= on NM_020822.3) | Splice Region (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- KDM3B | c.4843C>T p.H1615Y | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5C | c.4517del p.G1506Afs*38 | Frame Shift Del (DEL) | VAF 39/132 reads (30%) | called by mutect2, pindel, varscan2
- KDM6B | c.4909-3del | Splice Region (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- KDM8 | c.714A>C p.E238D | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIAA0319L | c.1508dup p.V504Cfs*26 | Frame Shift Ins (INS) | VAF 9/93 reads (10%) | called by mutect2, pindel
- KIAA0895L | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF26B | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- KIF2B | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF3B | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KIF5B | c.713T>A p.V238D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLC4 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLF3 | c.318del p.K106Nfs*21 | Frame Shift Del (DEL) | VAF 54/514 reads (11%) | called by mutect2, pindel, varscan2
- KLHL29 | c.1016_1017del p.E339Vfs*2 | Frame Shift Del (DEL) | VAF 32/173 reads (18%) | called by pindel, varscan2
- KLK4 | c.476-4C>A | Splice Region (SNP) | VAF 96/498 reads (19%) | called by muse, varscan2
- KMT2B | c.1919C>A p.S640Y | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); called by muse, mutect2
- KMT2D | c.10219_10221del p.F3407del | In Frame Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- KNDC1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT6A | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 93/633 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LAMC2 | c.2021G>A p.S674N | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LCE1F | c.92dup p.C33Vfs*4 | Frame Shift Ins (INS) | VAF 38/252 reads (15%) | called by mutect2, varscan2
- LIG4 | c.1880del p.K627Sfs*8 | Frame Shift Del (DEL) | VAF 45/405 reads (11%) | called by mutect2, pindel, varscan2
- LIPA | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LLGL1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- LRMDA | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRP1 | c.5564G>A p.G1855D | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRN2 | c.1978G>T p.G660C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- LTBR | c.543del p.S182Afs*33 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- LYZL4 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.188); called by muse, mutect2
- MAB21L3 | c.645_646del p.R215Sfs*10 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by pindel, varscan2
- MAOA | c.94T>A p.L32M | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1LC3A | c.41-1G>A p.X14_splice | Splice Site (SNP) | VAF 28/132 reads (21%) | called by muse, varscan2
- MAST3 | c.2392del p.V798* | Frame Shift Del (DEL) | VAF 85/507 reads (17%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.1639T>C p.W547R | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2
- MDN1 | c.7848_7851del p.D2618Sfs*9 | Frame Shift Del (DEL) | VAF 23/175 reads (13%) | called by mutect2, pindel, varscan2
- MED1 | c.2890G>A p.G964R | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MED13 | c.4600A>G p.T1534A | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2B | c.832del p.Q278Sfs*6 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- MEGF10 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFSD6L | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- MGAT4C | c.1345dup p.I449Nfs*4 | Frame Shift Ins (INS) | VAF 40/124 reads (32%) | called by mutect2, pindel, varscan2
- MINAR1 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- MIS18A | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, varscan2
- MNT | c.653+1del p.X218_splice | Splice Site (DEL) | VAF 45/227 reads (20%) | called by mutect2, pindel, varscan2
- MOSPD2 | c.1142G>A p.C381Y | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- MST1 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- MTMR12 | c.1985G>A p.S662N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC2 | c.1739C>A p.A580E | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0.04); called by muse, mutect2
- MUC5B | c.14631del p.V4879Wfs*2 | Frame Shift Del (DEL) | VAF 73/267 reads (27%) | called by mutect2, pindel, varscan2
- MUS81 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MYH9 | c.1559G>C p.G520A | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2
- MYO3B | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYOD1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYRFL | c.2270C>A p.P757H | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.618); called by muse, mutect2
- NAALAD2 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- NAGS | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NDUFS7 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFV3 | c.300_302del p.S101del (on ENST00000340344 / NM_001001503.2; = p.S466del on NM_021075.4) | In Frame Del (DEL) | VAF 44/304 reads (14%) | called by pindel, varscan2
- NECAB1 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- NEFM | c.2162del p.K721Rfs*18 | Frame Shift Del (DEL) | VAF 54/480 reads (11%) | called by mutect2, pindel, varscan2
- NEK10 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 52/252 reads (21%) | called by muse, mutect2, varscan2
- NEU1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NEU2 | c.1109dup p.Q371Afs*6 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- NIN | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- NINL | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NIPBL | c.5174dup p.F1726Vfs*3 | Frame Shift Ins (INS) | VAF 52/302 reads (17%) | called by mutect2, pindel, varscan2
- NKAP | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NLGN3 | c.2341del p.H781Mfs*14 (on ENST00000358741 / NM_181303.2; = p.H761Mfs*14 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/346 reads (17%) | called by mutect2, pindel, varscan2
- NMD3 | c.256del p.I86Sfs*5 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | called by mutect2, pindel, varscan2
- NOS1 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NPIPB9 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- NRXN3 | c.2061C>A p.S687R (on ENST00000335750 / NM_001330195.2; = p.S314R on NM_004796.6) | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NSMF | c.196del p.Q66Rfs*59 | Frame Shift Del (DEL) | VAF 88/295 reads (30%) | called by mutect2, pindel, varscan2
- NTN1 | c.1537T>G p.F513V | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTNG2 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUP43 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OBSL1 | c.4902del p.P1635Hfs*4 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel, varscan2
- ONECUT2 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR3A3 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C5 | c.237del p.V80Cfs*11 | Frame Shift Del (DEL) | VAF 41/340 reads (12%) | called by mutect2, pindel, varscan2
- OR4D2 | c.216T>G p.C72W | Missense Mutation (SNP) | VAF 116/815 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OR51S1 | c.333del p.F111Lfs*38 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by mutect2, pindel, varscan2
702 further variants in this file (199 protein-altering or splice-affecting, 298 silent, 205 other) are not listed here.
